Surgical pathology report (de-identified scan), TCGA case TCGA-FR-A3R1, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of North Carolina, specimen TCGA-FR-A3R1-01A (Primary Tumor).

[page 1 of 3]
UUID: C9C9SACS-2282-4C6C-A1C0-9D5F920AFB72

Diagnosis:

A: Sentinel lymph node #1, right axilla, removal

-No evidence of melanoma in 1 sentinel lymph node (0/1)
-Melan A and S100 protein immunostains and levels are negative
in all four
blocks

B: Sentinel lymph node #2, right axilla, removal

-No evidence of melanoma in 1 sentinel lymph node (0/1)
-Melan A and S100 protein immunostains and levels are negative
in both blocks

C: Sentinel lymph node #3, right axilla, removal

-No evidence of melanoma in 1 sentinel lymph node (0/1)
-Melan A and S100 protein immunostains and levels are negative

D: Skin, right arm, wide excision

Histologic type: Nodular melanoma

Breslow depth: 6.3 mm (6.3 cm)- this thickness is
substantially thicker than the initial biopsy Ulceration:
EXTENSIVELY PRESENT

Consumption of the epidermis: present

Margins: all margins are widely free

Clark level: V

Vertical growth phase: present

Mitoses: 3.75 per square mm

Tumor infiltrating lymphocytes: present, focally brisk

Regression: not identified

Lymphovascular space invasion: not identified

Satellite nodule: not identified

Perineural invasion: not identified

Coexisting nevus: not identified

Pigmentation: present, minimal

Solar elastosis: present, mild

Other features: necrosis is also present

AJCC Staging

pT4b

pN0

pMx

ICD-O-3

melanoma, nodular
8721/3

site: Skin, arm

C44.4

3-21-12 RD

This staging information is based on this pathologic specimen
and may be incomplete. A comprehensive review of all available

[page 2 of 3]
information is recommended to determine final staging.

Comment:

The frozen section diagnosis is confirmed.

Intraoperative Consult Diagnosis:
Frozen section was requested.

FSA1: Right axillary lymph node, biopsy
- No neoplasm identified

Clinical History:
-year-old with right arm melanoma.

Gross Description:
Received are four formalin-filled containers. Specimen A is submitted fresh for frozen section.

Container A: Received is a 3.0 x 2.1 x 1.0 cm lymph node. Representative section is frozen as FSA1. Grossly, this area is suspicious for hemorrhage?, remaining sections are submitted in blocks A2-A4,

Container B is additionally labeled "sentinel lymph node #2." Received is a brown/tan unoriented soft tissue fragment measuring 1.4 x 0.9 x 0.4 cm. The specimen is serially sectioned and submitted entirely in blocks B1 and B2,

Container C is additionally labeled "sentinel lymph node #3." Received is a single unoriented 1.2 x 1.1 x 0.7 cm brown/tan soft tissue fragment. The specimen is serially sectioned and submitted entirely in block C1,

Container D is additionally labeled "skin, right arm melanoma, wide excision."

Specimen fixation: formalin

Specimen type: wide excision

Tumor site: right arm

Orientation of the specimen: The specimen is oriented with a short stitch/superior designated as 12 o' clock, and a long stitch lateral designated as 9 o' clock.

[page 3 of 3]
Inking: yellow=12 o' clock to 3 o' clock, blue=3 o' clock to 6 o'clock, red=6 o' clock to 9 o' clock, green=9 o' clock to 12 o' clock, deep margin=black except for a central recessed area which is inked orange

Skin ellipse dimensions: 9.7 x 8.9 cm

Tumor size and description: The tumor is 10.5 x 8.7 x 6.3 cm. The tumor overhangs the skin ellipse at 3 o' clock x approximately 2.5 cm. The tumor is exophytic, raised with lobulated borders.

Microscopic pigmentation: There are multiple white/tan nodules ranging in diameter from 0.2 to 0.3 cm towards the posterior aspect of the tumor, and several foci of hemorrhages mainly towards the posterior aspect of the tumor.

Satellite nodules: none identified

Distance of tumor from margins: 1.9 cm at the 12 o' clock, 2.1 cm at 3 o' clock, 2.4 cm at 6 o' clock, and 1.8 cm at 9 o' clock

Digital photograph taken: not taken

Tissue submitted for special investigation: none

Block summary:

D1,D2 - deep en face margin from 12 o' clock to 3 o' clock
D3,D4 - deep en face margin from 3 o' clock to 6 o' clock
D5-D7 - deep en face margin from 6 o' clock to 9 o' clock
D8,D9 - deep en face margin from 9 o' clock to 12 o' clock
D10-D21- radial perpendicular sections from the biopsy site to corresponding clock number margin: D10, 12 o' clock; D11, 1 o' clock; etc..., D21=11 o' clock
D22-D25 representative sections from the tumor, abutting the orange margin

Light Microscopy:

Light microscopic examination is performed. S100 protein and Melan A immunostains were performed on each sentinel lymph node block and were medically necessary. All are negative for metastatic melanoma. S100 and Melan A were also utilized to evaluate a small area in block D11. These stains are negative thereby arguing against a satellite metastasis.

Source: NCI Genomic Data Commons file a3413b48-8eb3-4be8-9f7e-8c0196a0ce9c (TCGA-FR-A3R1.C9C95AC5-22B2-4C6C-A1C0-9D5F920AFB72.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).